Somatic mutation profile of tumor specimen TCGA-B0-5100-01A (aliquot TCGA-B0-5100-01A-01D-1421-08) from TCGA case TCGA-B0-5100, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 72.5 years (26,478 days).
Specimen TCGA-B0-5100-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2282f570-5aaa-4e2c-b5d5-40598cde32a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5100-11A (Solid Tissue Normal), aliquot TCGA-B0-5100-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7031450c-817b-48ab-905f-e9857e929b7c

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 24, Silent 9, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 122/376 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs188113151; called by muse, mutect2, varscan2
- AL592490.1 | c.2174C>T p.T725I | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV69426716; called by muse, mutect2, varscan2
- CD200 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59863624; called by muse, mutect2, varscan2
- CDKN2AIPNL | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1277533198, COSV67655146; called by muse, mutect2, varscan2
- CNOT2 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV57503911; called by muse, mutect2, varscan2
- COL4A3 | c.4500G>A p.M1500I | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67416402; called by muse, mutect2, varscan2
- CORO7 | c.2772G>T p.W924C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52031292; called by muse, mutect2, varscan2
- CYP11A1 | c.722T>C p.F241S | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51432753; called by muse, mutect2, varscan2
- FERMT2 | c.1192A>T p.T398S | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV58407844; called by muse, mutect2, varscan2
- KLF8 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63848092; called by muse, mutect2, varscan2
- MAP3K4 | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170397798, COSV62335010; called by muse, mutect2, varscan2
- MASP1 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1328049833, COSV56224686; called by muse, mutect2, varscan2
- MRPS18B | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52541805; called by muse, mutect2, varscan2
- MTOR | c.5917A>T p.I1973F | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV63873321; called by muse, varscan2
- NLRP3 | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV60226677; called by muse, varscan2
- PCED1B | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV71395361; called by muse, mutect2, varscan2
- PCF11 | c.1897T>C p.S633P | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV53533378; called by muse, mutect2, varscan2
- PCSK2 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.362); catalogued as COSV52730032; called by muse, mutect2, varscan2
- RYR1 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs929824581, COSV62094113, COSV62101088; called by muse, mutect2, varscan2
- RYR2 | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598439, COSV63666259; called by muse, mutect2, varscan2
- SMURF1 | c.1449C>G p.P483= | Splice Region (SNP) | VAF 41/113 reads (36%) | catalogued as COSV100742561, COSV63158088; called by muse, mutect2, varscan2
- SRSF11 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63937218; called by muse, mutect2, varscan2
- TTN | c.99266C>T p.T33089I (on ENST00000591111; = p.T25665I on NM_003319.4) | Missense Mutation (SNP) | VAF 67/262 reads (26%) | PolyPhen benign (0.361); catalogued as COSV60146194; called by muse, mutect2, varscan2
- UNC5D | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54805099; called by muse, mutect2, varscan2
- ZNF385B | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs371958237; called by muse, mutect2
- APCS | c.132G>A p.P44= | Silent (SNP) | VAF 63/196 reads (32%) | catalogued as rs371650621; called by muse, mutect2, varscan2
- CDKN2AIPNL | c.135G>T p.L45= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV67655153; called by mutect2, varscan2
- DHX32 | c.1935G>A p.Q645= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as COSV52941106; called by muse, mutect2
- DOCK3 | c.964C>T p.L322= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV56529498; called by muse, mutect2, varscan2
- KRTAP4-2 | c.87C>A p.T29= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV66658687; called by muse, mutect2, varscan2
- NOS3 | c.1524G>A p.S508= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs61734203; called by muse, mutect2, varscan2
- PCDHB16 | c.1377C>T p.F459= | Silent (SNP) | VAF 73/210 reads (35%) | catalogued as rs782620895, COSV53358498; called by muse, mutect2, varscan2
- TBC1D12 | c.2169A>G p.L723= | Silent (SNP) | VAF 86/262 reads (33%) | catalogued as COSV56554995; called by muse, mutect2, varscan2
- UPF2 | c.444C>T p.N148= | Silent (SNP) | VAF 64/500 reads (13%) | catalogued as COSV62661540; called by muse, mutect2, varscan2
